CCDI case PBCGNR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bladder.
https://portal.gdc.cancer.gov/cases/3d62a87c-7563-4ea2-8f45-93c837066fdf

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Bladder, NOS; Age at diagnosis: 1.6 years (580 days).

Biospecimens (3 samples)
- Samples 0DRIW1, 0DRIW7 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRIWH: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
